TCGA case TCGA-3U-A98J — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Chicago. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a61ea4c7-2506-4d56-aeb5-edf83199d421

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 741 days (2.0 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.7 years (20,338 days); Year of diagnosis: 2012; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 741 days (2.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed; Days to treatment start: 137 days; Days to treatment end: 228 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 627 days (1.7 years); Days to treatment end: 627 days (1.7 years); Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 57.4 years (20,958 days); Days to diagnosis: 620 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Days to follow up: 485 days (1.3 years); Disease response: With Tumor.
- Day 620 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 620 days (1.7 years).
- Days to follow up: 741 days (2.0 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 10.2; Timepoint: Prior to Treatment.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 2; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.9; Blood test normal range upper: 1.4].

Exposures
- Occupation type: Manufacturing Labourers.
- Exposure type: Asbestos; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3U-A98J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-3U-A98J-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-3U-A98J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3U-A98J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Machinist in a molding company, home remodeler, and brake fixer; Performance status timing: Post-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Pemetrexed (Alimta); Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Clinical trial drug classification: anti-CTLA4 monoclonal antibody.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 741 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 741 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 741 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3U-A98J-01A-11D-A39Q-01): tumor purity 0.57, ploidy 1.97, whole-genome doublings 0.
